Somatic mutation profile of tumor specimen 0D9Z2M from CCDI case PBBIZT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 5.8 years (2,122 days).
Specimen 0D9Z2M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7652c12e-28bc-4aba-8dec-0b5a74286891.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9Z2N (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6e47b84-225b-4d96-833f-6fa57ee06642

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 3, 3'UTR 2, Silent 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 135/563 reads (24%) | catalogued as COSV57431544; called by muse, mutect2, varscan2
- ACSF2 | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 125/521 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SP5 | c.207C>A p.L69= | Silent (SNP) | VAF 7/111 reads (6%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 14/137 reads (10%) | called by mutect2, varscan2
- CEP78 | c.1069+59A>G | Intron (SNP) | VAF 13/202 reads (6%) | called by muse, mutect2
- LRRC63 | c.*79T>G | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- TMSB4X | c.*40G>A | 3'UTR (SNP) | VAF 11/584 reads (2%) | catalogued as COSV101020323; called by muse, mutect2
